Somatic mutation profile of tumor specimen HTMCP-03-06-02211-01B (aliquot HTMCP-03-06-02211-01B-01D-6925) from CGCI case HTMCP-03-06-02211, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3.
Specimen HTMCP-03-06-02211-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3912f068-005a-4bb7-8a2d-ade4b7507ba5.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02211-10A (Blood Derived Normal), aliquot HTMCP-03-06-02211-10A-01D-6194; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/326c9980-5641-4ebc-83f1-99ea2bb51dbc

The open-access MAF lists 20 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Splice Site 3, Nonsense Mutation 3, Silent 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.2890C>T p.R964* | Nonsense Mutation (SNP) | VAF 17/79 reads (22%) | catalogued as rs754497896; called by muse, mutect2, varscan2
- EP300 | c.3127C>T p.Q1043* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV54337722; called by muse, mutect2, varscan2
- FAM47B | c.287A>T p.K96M | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61456592; called by muse, mutect2, varscan2
- HPS5 | c.1252G>A p.E418K (on ENST00000349215 / NM_181507.2; = p.E304K on NM_007216.4) | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); catalogued as rs1461927795; called by muse, mutect2
- SCN2A | c.1837G>A p.V613M | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769069833, COSV51834027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP26 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV63709530; called by muse, mutect2, varscan2
- ADGRL3 | c.3559A>T p.I1187L (on ENST00000506720 / NM_001322402.2; = p.I1119L on NM_015236.6) | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL7A1 | c.3403+1G>A p.X1135_splice | Splice Site (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- EP300 | c.5400dup p.C1801Mfs*82 | Frame Shift Ins (INS) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- FAT1 | c.11320C>T p.H3774Y | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FNDC7 | c.366C>A p.S122R | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MED12 | c.2188C>T p.R730* | Nonsense Mutation (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- NUP188 | c.373-2A>G p.X125_splice | Splice Site (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
- PIK3R1 | c.1709_1714del p.L570_I571del (on ENST00000521381 / NM_181523.3; = p.L300_I301del on NM_181504.4) | In Frame Del (DEL) | VAF 18/131 reads (14%) | called by mutect2, pindel, varscan2
- RBM25 | c.2295A>G p.I765M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TENM1 | c.7706G>A p.G2569E | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRA2B | c.163_170+36del p.X55_splice | Splice Site (DEL) | VAF 18/139 reads (13%) | called by mutect2, pindel
- ZNF831 | c.1586C>T p.T529M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- GDPD4 | c.834G>A p.L278= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as rs774064639, COSV60021646; called by muse, mutect2, varscan2
- ICE1 | c.3426G>A p.E1142= | Silent (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
